CCDI case PBCJMN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/61593907-1922-4da3-9b36-789617d6f6e6

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,771 days).

Biospecimens (3 samples)
- Sample 0DTC5P: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTC5X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTC61: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
